Somatic mutation profile of tumor specimen ALCH-B2OD-TTP1-A (aliquot ALCH-B2OD-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2OD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.6 years (26,516 days).
Specimen ALCH-B2OD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 180557a5-b944-4862-be03-7bf9b499a4c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OD-NB1-A (Blood Derived Normal), aliquot ALCH-B2OD-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e522be0-06dc-459d-8709-dfd36c6b726e

The open-access MAF lists 103 somatic variants for this specimen: 69 protein-altering or splice-affecting, 22 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 22, Nonsense Mutation 7, Frame Shift Del 6, Intron 5, 5'UTR 4, 3'UTR 2, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 84/291 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 82/379 reads (22%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- NUP93 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 43/157 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs528073782, COSV57428317; called by muse, mutect2, varscan2
- ANKRD33B | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs1000222233; called by muse, mutect2, varscan2
- ARHGAP30 | c.2768G>A p.R923H (on ENST00000368013 / NM_001025598.2; = p.R712H on NM_181720.3) | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748205506, COSV63519608; called by muse, mutect2
- ASTN1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 67/485 reads (14%) | catalogued as COSV99920397; called by muse, mutect2, varscan2
- CSMD2 | c.1270C>G p.Q424E | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53948375; called by muse, varscan2
- EBNA1BP2 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as rs759104670; called by muse, mutect2, varscan2
- FOXO4 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58575648; called by muse, mutect2, varscan2
- HECTD4 | c.8471T>C p.I2824T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1018227288; called by muse, mutect2, varscan2
- HMCN2 | c.11402G>A p.R3801H | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs1337522827; called by muse, mutect2
- IQSEC3 | c.1403C>T p.A468V (on ENST00000538872 / NM_001170738.2; = p.A165V on NM_015232.1) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1555087651, COSV100407361; called by muse, mutect2, varscan2
- KCNA4 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60251569, COSV60252848; called by muse, mutect2, varscan2
- KDELR3 | c.366_369del p.F122Lfs*15 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs753780926; called by mutect2, pindel
- KY | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as rs554935589; called by muse, mutect2
- LAMA2 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV70337375, COSV70343666; called by muse, varscan2
- LZTS1 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747202756; called by muse, mutect2, varscan2
- NSUN6 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV66032468; called by muse, mutect2, varscan2
- OR5B3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV58678151; called by muse, mutect2, varscan2
- PCDHB10 | c.971del p.G324Vfs*11 | Frame Shift Del (DEL) | VAF 61/274 reads (22%) | catalogued as COSV53381632; called by mutect2, pindel, varscan2
- PCDHB7 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 98/950 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs782586618, COSV50769229; called by muse, varscan2
- PLD2 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs116011301, COSV54005552; called by muse, mutect2, varscan2
- RBM15B | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs782771704; called by muse, mutect2, varscan2
- RIPOR3 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201920244, COSV50388286; called by muse, mutect2, varscan2
- RSKR | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs148150453, COSV56382032, COSV56383106; called by muse, varscan2
- SCCPDH | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 32/195 reads (16%) | catalogued as COSV63618513; called by muse, mutect2, varscan2
- SLC4A10 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as rs780653423, COSV55784095; called by muse, mutect2, varscan2
- SLC6A11 | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV54393237; called by muse, mutect2, varscan2
- SOX7 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs948849319; called by muse, mutect2, varscan2
- SPTBN5 | c.1396G>T p.V466F | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV58019758; called by muse, mutect2, varscan2
- SYN3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775238041, COSV60509192; called by muse, mutect2, varscan2
- VPS13A | c.6028G>A p.E2010K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.479); catalogued as rs776345066, COSV62437238; called by muse, mutect2
- WDTC1 | c.1905G>A p.M635I (on ENST00000319394 / NM_001276252.2; = p.M634I on NM_015023.5) | Missense Mutation (SNP) | VAF 102/611 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60089674; called by muse, mutect2, varscan2
- BORA | c.1768G>A p.E590K (on ENST00000613797; = p.E515K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC175 | c.1768A>T p.R590* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- CDC26 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CDR2L | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CHN1 | c.244T>A p.Y82N | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2
- CHRNG | c.280T>A p.Y94N | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- COL5A3 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPXCR1 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CUBN | c.2816C>G p.S939* | Nonsense Mutation (SNP) | VAF 40/180 reads (22%) | called by muse, mutect2, varscan2
- CYP3A5 | c.799-4C>G | Splice Region (SNP) | VAF 31/124 reads (25%) | called by muse, varscan2
- DISP3 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- EMILIN2 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- EVC2 | c.2466G>C p.Q822H | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCGR2B | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 45/564 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- GOLGA8T | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GRPR | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GTF3C3 | c.1376G>A p.W459* | Nonsense Mutation (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.1004del p.N335Tfs*17 | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | called by mutect2, pindel, varscan2
- KCNH5 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- KRT15 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- LMBRD1 | c.1311G>A p.M437I (on ENST00000649011; = p.M415I on NM_018368.4) | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.415); called by muse, varscan2
- LRRC25 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEB6 | c.1163del p.P388Hfs*8 | Frame Shift Del (DEL) | VAF 58/188 reads (31%) | called by mutect2, varscan2
- MUC16 | c.33983G>C p.R11328T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- MUC16 | c.33904G>C p.E11302Q | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.115); called by muse, varscan2
- PCDHA13 | c.1667T>C p.L556P | Missense Mutation (SNP) | VAF 167/647 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RND1 | c.491_507del p.Y164Ffs*23 | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | called by pindel, varscan2*
- SETD1B | c.1680del p.S561Rfs*47 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by pindel, varscan2
- SRR | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- STN1 | c.1104C>G p.F368L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SYNDIG1 | c.493A>C p.S165R | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.12334C>T p.Q4112* (on ENST00000367255 / NM_182961.4; = p.Q4041* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 53/258 reads (21%) | called by muse, mutect2, varscan2
- TRAV23DV6 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- TTF2 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCAN | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WHRN | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 93/487 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- AGT | c.1098C>G p.L366= | Silent (SNP) | VAF 70/449 reads (16%) | called by muse, mutect2, varscan2
- ARID1A | c.3318G>A p.K1106= | Silent (SNP) | VAF 66/444 reads (15%) | catalogued as COSV61377526; called by muse, mutect2, varscan2
- C5orf34 | c.909C>T p.S303= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs752508518, COSV60931400; called by muse, varscan2
- CSMD3 | c.9120T>C p.H3040= (on ENST00000297405 / NM_001363185.1; = p.H2871= on NM_052900.3) | Silent (SNP) | VAF 86/314 reads (27%) | catalogued as rs1045868628; called by muse, mutect2, varscan2
- GON4L | c.2286G>A p.L762= | Silent (SNP) | VAF 52/432 reads (12%) | catalogued as COSV99673955, COSV99675580; called by muse, mutect2, varscan2
- LBP | c.1011G>T p.L337= | Silent (SNP) | VAF 69/282 reads (24%) | called by muse, mutect2, varscan2
- LRRC14B | c.480C>T p.A160= | Silent (SNP) | VAF 34/257 reads (13%) | catalogued as rs1269980203, COSV52044356; called by muse, mutect2, varscan2
- MDGA2 | c.2170C>T p.L724= (on ENST00000399232 / NM_001113498.2; = p.L426= on NM_182830.4) | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs770306806, COSV62079699; called by muse, mutect2, varscan2
- NFATC1 | c.1533C>T p.L511= | Silent (SNP) | VAF 86/316 reads (27%) | called by muse, mutect2, varscan2
- PCSK6 | c.429G>A p.V143= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as rs773902223; called by muse, mutect2, varscan2
- PRR14L | c.5442C>T p.D1814= | Silent (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
- PSMA7 | c.157C>T p.L53= | Silent (SNP) | VAF 26/233 reads (11%) | called by muse, mutect2, varscan2
- PTPRU | c.600C>T p.V200= | Silent (SNP) | VAF 44/249 reads (18%) | called by muse, mutect2, varscan2
- SLC10A3 | c.762G>A p.L254= | Silent (SNP) | VAF 91/329 reads (28%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3528C>T p.S1176= | Silent (SNP) | VAF 69/274 reads (25%) | catalogued as rs573885719; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SULF2 | c.222C>T p.G74= | Silent (SNP) | VAF 17/420 reads (4%) | catalogued as rs983061029, COSV63413644; called by muse, mutect2
- TACC3 | c.1575C>T p.F525= | Silent (SNP) | VAF 59/224 reads (26%) | called by muse, mutect2, varscan2
- TAT | c.418C>T p.L140= | Silent (SNP) | VAF 44/286 reads (15%) | called by muse, varscan2
- TBC1D31 | c.1380C>T p.L460= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs777638136; called by muse, mutect2
- TMEM174 | c.378C>T p.N126= | Silent (SNP) | VAF 93/324 reads (29%) | called by muse, mutect2, varscan2
- TTBK1 | c.1650G>A p.T550= | Silent (SNP) | VAF 111/257 reads (43%) | catalogued as rs754522479; called by muse, mutect2, varscan2
- ZNF692 | c.1026G>A p.R342= | Silent (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
- ATP6V1G1 | c.-16C>T | 5'UTR (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- CSH2 | c.456+47A>C | Intron (SNP) | VAF 38/360 reads (11%) | catalogued as rs139723494, COSV100400181; called by muse, mutect2, varscan2
- HSP90AA4P | n.1982C>T | RNA (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- LZTFL1 | c.-33C>G | 5'UTR (SNP) | VAF 32/297 reads (11%) | called by muse, mutect2, varscan2
- MPHOSPH6 | c.255+80C>G | Intron (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- PDZRN4 | c.*2C>A | 3'UTR (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100115725; called by muse, mutect2
- RAB3GAP2 | c.-13G>A | 5'UTR (SNP) | VAF 101/588 reads (17%) | called by muse, mutect2, varscan2
- SLC9A5 | c.733+14C>T | Intron (SNP) | VAF 92/329 reads (28%) | called by muse, mutect2, varscan2
- TBC1D30 | c.*1054C>A | 3'UTR (SNP) | VAF 46/210 reads (22%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.1196+144G>C | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- WDR1 | c.-35C>T | 5'UTR (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- XAF1 | c.422-179G>C | Intron (SNP) | VAF 59/290 reads (20%) | called by muse, mutect2, varscan2
